Gene-level copy-number profile of tumor specimen C3L-09086-02 from CPTAC case C3L-09086, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 84.8 years (30,976 days).
Specimen C3L-09086-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aaba852b-71ab-4774-bfa1-3bd7e3b5dacb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09086-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,739 have no estimate.
https://portal.gdc.cancer.gov/files/ace57351-dc1c-4910-8a85-d560a8332047

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 17,912; copy number 2: 34,273; copy number 3: 6,401; copy number 4: 161; copy number 5: 25; copy number 7: 48; copy number 8: 12.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:184,334,292–184,559,783, 8 genes: LINC02363, LINC02362, IRF2, SNORD79, AC099343.2, IRF2-DT, LINC02427, AC099343.1.
- chr14:18,967,434–19,714,332, 42 genes: POTEM, AL929601.3, RNU6-1239P, AL589182.1, GRAMD4P4, DUXAP9, AL589182.3, AL589743.3, NBEAP5, AL589182.2, OR11H13P, AL589743.2, AL589743.4, CDRT15P13, NBEAP6, AL589743.1, TOMM40P1, DUXAP10, BMS1P17, AL929602.1, LINC01297, GRAMD4P3, POTEG, AL512624.2, RNU6-1268P, MED15P6, NF1P4, AL512310.11, AL512624.1, NF1P11, AL512310.3, AL512310.10, AL512310.8, AL512310.4, AL512310.5, AL512310.6, AL512310.9, AL512310.7, AL512310.2, ARHGAP42P4, AL512310.1, OR11H2.
- chr14:23,969,874–24,051,377, 2 genes (within-gene range 0–1): DHRS4L2, AL136419.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 75 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:59,847,438–59,950,574, 5 genes, copy number 5 (within-gene range 3–5): RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21.
- chr22:40,824,535–42,155,001, 70 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,793. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
